Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7211, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7211-01A (Primary Tumor).

[page 1 of 2]
Collection Date: [REDACTED]
Hospital of Origin [REDACTED]
Copy [REDACTED]

QC Pathologist:

TCGA-HC-7211

FINAL PATHOLOGIC DIAGNOSIS:

A. Right and left pelvic lymph node dissections:

Ten benign hyperplastic regional lymph nodes (0/10).

B. Radical prostatectomy:

Carcinoma.

Tumor Characteristics:

1. Histologic type: Adenocarcinoma, conventional type.
2. Prostate size: 4.8 x 3.5 x 3.0 cm weighing 34.9 grams.

3. Tumor quantitation: estimated 5 to 10% of gland volume involved.

4. Gleason grade:

- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 7/10.

5. Extraprostatic extension: Not identified.

6. Seminal vesicle involvement: Not identified.

7. Lymphovascular space invasion: Not identified.

8. High grade PIN: Present.

9. Treatment effect: Not identified.

Surgical Margin Status:

1. Margins uninvolved.

Lymph Node Status: (utilizing specimen A)

1. Total number of lymph nodes received: Ten.

2. Total number of lymph nodes containing metastatic carcinoma: None (0/10).

Other:

1. Other significant findings: None.

2. pTNM stage: pT2c,N0.

COMMENTS:

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Right and left pelvic lymph nodes

B. Prostate

[page 2 of 2]
PROCEDURAL DEMOGRAPHICS:

Date of Procedure: [REDACTED]

Accession Date/Time: [REDACTED]

GROSS DESCRIPTION:

A. The specimen is received in a single formalin-filled container labeled with the patients name "right and left pelvic lymph nodes," and consists of a 6.0 x 4.5 x 2.5 cm, aggregate of yellow-tan, fibrofatty soft tissue. On palpation, multiple firm fatty possible lymph nodes are identified ranging from 0.1 up to 2.0 cm in greatest dimension. They are entirely submitted in cassettes A1-4, labeled [REDACTED] designated as follows: A1, five whole possible lymph nodes; A2, four whole possible lymph nodes; A3 and 4, one whole possible bisected lymph node in each cassette.

B. The specimen is received in a single formalin-filled container labeled with the patients name "prostate," and contains a 34.9 gm, 4.8 x 3.5 x 3.0 cm prostate received with attached bilateral adnexa having overall dimensions of 6.5 x 3.5 x 0.5 cm. The capsule is tan-gray and shaggy. The specimen is inked as follows: right side blue, left side black. The base and apical margins are coned and serially sectioned. The remainder of the gland is serially sectioned from apex to base to reveal a 1.5 x 1.0 x 0.8 cm, well-circumscribed, yellow-tan nodule located in the right posterior quadrant. This nodule abuts the inked capsule. Additionally, a 2.5 x 1.5 x 1.0 cm, ill-defined area of tan-orange discoloration is present within the right and left posterior quadrants. This area approaches to within 0.5 cm of the base margin and to within 0.2 cm of the right prostate/seminal vesicle junction. The remainder of the cut surface is pink-tan and focally cystic with diffuse periurethral nodularity. No additional lesions or calculi are identified. Representative sections are submitted in cassettes B1-18, labeled [REDACTED] designated as follows: 1, right prostate/seminal vesicle junction; 2, left prostate /seminal vesicle junction; 3 and 4, apical margin, perpendicular; 5 and 6, base margin, perpendicular; 7-9, right anterior, apex to base; 10-12, right posterior, apex to base; 13-15, left anterior, apex to base; 16-18, left posterior, apex to base. Additionally, a yellow and a green cassette are submitted for genomics research, each labeled [REDACTED]

INTRA-PROCEDURE CONSULTATION:

MICROSCOPIC DESCRIPTION:

Source: NCI Genomic Data Commons file e918fb7a-e369-4fc5-97a5-e2da91c54269 (TCGA-HC-7211.47E4122A-96E7-43D6-9242-AD7BFF977BA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).